Surgical pathology report (de-identified scan), TCGA case TCGA-30-1880, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Harvard, specimen TCGA-30-1880-01A (Primary Tumor).

[page 1 of 2]
Accession Number: [REDACTED]

Report Status: Final

Type: Surgical Pathology

Pathology Report

UTERUS WITH OR WITHOUT TUBES & OVARIES NEOPLASTIC

Accessioned On: [REDACTED]

DIAGNOSIS:

SPECIMEN LABELED "RIGHT OVARY" (incl. FSA):

PAPILLARY SEROUS ADENOCARCINOMA (15 cm), grade 3 (of 3).

Tumor involves the surface.

Lymphovascular invasion is present.

SPECIMEN LABELED "OMENTAL BIOPSY":

METASTATIC ADENOCARCINOMA within omental adipose tissue.

SPECIMEN LABELED "TUMOR FROM BLADDER":

METASTATIC ADENOCARCINOMA, surface of bladder.

SPECIMEN LABELED "LEFT ADNEXA":

METASTATIC ADENOCARCINOMA located on ovarian surface and lumen of fallopian tube.

SPECIMEN LABELED "UTERUS & CERVIX" (67g):

Cervix:

METASTATIC ADENOCARCINOMA in paracervical soft tissue.

Endometrium:

Inactive endometrium.

Myometrium:

Leiomyomata (1.5 cm).

Serosa:

METASTATIC ADENOCARCINOMA on serosal surface.

SPECIMEN LABELED "PELVIC PERITONEUM WITH TUMOR":

METASTATIC ADENOCARCINOMA within adipose tissue.

SPECIMEN LABELED "RIGHT EXTERNAL ILIAC NODE":

Two (2) of two (2/2) lymph nodes with METASTATIC ADENOCARCINOMA.

CLINICAL DATA:

History: None given.

Operation: Exploratory laparotomy, TAH/BSO, omentectomy, pelvic lymph node sampling, peritoneal biopsies

Clinical Diagnosis: Pelvic mass

TISSUE SUBMITTED: 1. Right ovary (FS)

2. Omentum biopsy

3. Tumor from bladder

4. Left adnexa

5. Uterus and cervix

6. Pelvic peritoneum with tumor

7. Right external iliac node

O.R. CONSULTATION:

SPECIMEN LABELED "RIGHT OVARY" (FSA):

Papillary serous adenocarcinoma.

GROSS DESCRIPTION:

The specimen is received fresh, in 7 parts, each labeled with the patient's name and unit number.

Part 1, "right ovary", consists of a 64g gram ovary (15 x 14 x 9 cm) that has a fibrocystic lesion filled with hemorrhagic fluid. The inner lining of the cystic lesion has multiple papillary projections. A representative section has been submitted as "FSA".

Micro 1 - FSA remnant, 1 frag, ESS.

Micro 2-4 - representative sections of ovarian cyst, 5 frags, RSS.

Printed:

[page 2 of 2]
Part 2, "omentum biopsy", consists of one fragment of yellow omentum (15 x 9 x 1.2 cm). Multiple white, hard nodules (up to 1.2 cm in greatest diameter) are identified within the omental tissue. Representative sections are submitted for analysis.

Micro 5-8 - omentum with nodules, multiple frags, RSS.

Part 3, "tumor from bladder", consists of a fragment of white/tan gelatinous soft tissue (4 x 2 x 0.4 cm) that has multiple small white fibrous nodules (up to 0.8 cm in greatest dimension) attached to what appears to be the serosal surface.

Micro 9 - 50% of tumor from bladder, 2 frags, RSS.

Part 4, "left adnexa", consists of one fragment of soft tissue (5 x 4 x 1.5 cm) including an ovary (2 x 1 x 1.5 cm) along with a fallopian tube (6 cm in length). Within the fallopian tube are multiple white, hard nodules (2.2 x 1.5 x 1.0 cm in length). Within the ovary, there is white, poorly circumscribed, fibrous, hard tissue that may represent tumor.

Micro 10 - left ovary with tumor, 1 frag, RSS.

Micro 11 - fallopian tube with tumor, 4 frags, RSS.

Part 5, "uterus with cervix", consists of a 67g TAH specimen (7 x 5 x 3 cm) with an exocervix (3.5 x 2 cm) with a 1.5 cm slit-like os and an endocervical canal (1.8 cm in length). The endometrium measures 0.4 cm in average thickness and the myometrium is 1.4 cm in thickness. Leiomyomata (up to 1.5 cm) are identified in the subserosal surface of the specimen. On the serosal surface of the uterus, possible tumor implants (up to 0.8 cm in greatest dimension) are identified, both anteriorly and posteriorly. No tumor-like implants are seen within the mucosal surface, although there are leiomyomata (up to 2.5 cm in greatest dimension) extending into the mucosa.

Micro 12 - anterior cervix, 1 frag, RSS.

Micro 13 - posterior cervix, 1 frag, RSS.

Micro 14 - anterior & posterior LUS with nodules, 2 frags, RSS.

Micro 15-16 - anterior endometrium, serosa & myometrium, 2 frags, RSS.

Micro 17-18 - posterior endometrium, serosa & myometrium along with serosal tumor implants, 3 frags, RSS.

Part 6, "pelvic peritoneum with tumor", consists of multiple fragments of yellow/white soft tissue (3.5 x 2 x 1 cm in dimensions). On the surface of this tissue are multiple white, hard nodules (up to 0.4 cm in greatest dimension). 50% of the tissue is submitted for analysis.

Micro 19 - tissue from pelvic peritoneum with tumor, multiple frags, RSS.

Part 7, "right external iliac node", consists of two yellow fibroadipose tissue (3 x 1.5 x 1.3 cm). One possible lymph node identified within the tissue bisected and entirely submitted.

Micro 20 - right external iliac node tissue, multiple frags, ESS.

Reports to: [REDACTED]

SPECIMEN TYPE: UTERUS WITH OR WITHOUT TUBES & OVARIES, NEOPLASTIC
ADDITIONAL SPECIMEN TYPE: OMENTUM BIOPSY
ADDITIONAL SPECIMEN TYPE: SOFT TISSUE BIOPSY
ADDITIONAL SPECIMEN TYPE: PERITONEUM BIOPSY
ADDITIONAL SPECIMEN TYPE: LYMPH NODE BIOPSY

Source: NCI Genomic Data Commons file 7bfbbd8d-5f50-4864-a2ef-1a085b255344 (TCGA-30-1880.D23622FE-9648-422D-AE92-B21F9B6E5A51.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).